Gene-level copy-number profile of tumor specimen TCGA-29-2431-01A from TCGA case TCGA-29-2431, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 59.8 years (21,833 days).
Specimen TCGA-29-2431-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.49faae6b-279a-4dec-af44-25fd7e00a8e9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-2431-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cb2f7693-4d97-4036-94ce-84bedee21d23

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 4,162; copy number 2: 16,242; copy number 3: 25,359; copy number 4: 9,537; copy number 5: 1,947; copy number 6: 1,785; copy number 7: 385; copy number 8: 333; copy number 10: 4; copy number 11: 13; copy number 14: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-2431-01A-01D-1043-01): tumor purity 0.88, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 752 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:71,373,938–72,826,041, 7 genes, copy number 8 (within-gene range 5–8): AC007878.1, RNU6-105P, DYSF, RPS20P10, CYP26B1, EXOC6B, RPS15AP13.
- chr2:76,595,413–82,609,977, 51 genes, copy number 7: RN7SKP164, AC068616.2, AC068616.3, AC068616.1, LRRTM4, RNA5SP98, AC079117.1, LRRTM4-AS1, AC013716.1, AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1.
- chr5:50,396,192–51,394,730, 17 genes, copy number 14: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1.
- chr5:52,579,555–52,959,209, 7 genes, copy number 11 (within-gene range 3–11): MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1.
- chr8:74,234,700–75,352,327, 19 genes, copy number 7 (within-gene range 5–7): JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6.
- chr8:104,981,164–105,196,969, 5 genes, copy number 8: AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1.
- chr9:72,521,608–72,838,297, 1 gene, copy number 8 (within-gene range 6–8): TMC1.
- chr9:72,741,152–73,579,498, 8 genes, copy number 8: RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1, DPP3P2, AL451127.2, AL451127.1.
- chr9:75,401,889–76,362,975, 4 genes, copy number 10 (within-gene range 2–10): AL158073.1, AL353780.1, OTX2P1, PCSK5.
- chr12:752,579–4,694,317, 96 genes, copy number 7–8 (broad region; genes not listed).
- chr12:69,359,710–72,670,758, 53 genes, copy number 7–11 (within-gene range 4–11): YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35.
- chr18:44,039,471–44,071,701, 2 genes, copy number 7: AC083760.1, RNA5SP455.
- chr20:34,194,569–51,131,667, 463 genes, copy number 7–8 (broad region; genes not listed).
- chr22:29,603,556–30,177,075, 19 genes, copy number 8: NF2, RPEP4, AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51.

Autosomal genes at a single copy (total copy number 1): 1,923. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
